Somatic mutation profile of tumor specimen 0DF86I from CCDI case PBBRVL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 5.2 years (1,896 days).
Specimen 0DF86I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e072a6dd-ed09-4c90-a72d-2281ae77113a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF86J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ede425a-0161-4cd4-96ad-1ba306d77eed

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Splice Site 2, Intron 1, Frame Shift Del 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM22 | c.1392+1del p.X464_splice | Splice Site (DEL) | VAF 148/723 reads (20%) | catalogued as COSV99716135; called by mutect2, varscan2
- C20orf96 | c.346C>T p.R116* (on ENST00000360321 / NM_153269.3; = p.R115* on NM_080571.1) | Nonsense Mutation (SNP) | VAF 128/482 reads (27%) | catalogued as rs1423234855; called by muse, mutect2, varscan2
- GIGYF1 | c.574C>G p.R192G | Missense Mutation (SNP) | VAF 273/1073 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs754929045; called by muse, mutect2, varscan2
- SP140 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 128/256 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149750664; called by muse, mutect2, varscan2
- UPB1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 173/682 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs753638837, COSV100387023; called by muse, mutect2, varscan2
- ZNF516 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 72/341 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs545742302, COSV71586843; called by muse, mutect2, varscan2
- HIPK1 | c.-2del | Splice Site (DEL) | VAF 40/146 reads (27%) | called by mutect2, varscan2
- PLXNA4 | c.3073del p.R1025Gfs*65 | Frame Shift Del (DEL) | VAF 230/948 reads (24%) | called by mutect2, varscan2
- COL7A1 | c.7381-50G>A | Intron (SNP) | VAF 128/267 reads (48%) | catalogued as rs371941592; called by muse, mutect2, varscan2
- ODF2 | chr9:128456069 C>T | 5'Flank (SNP) | VAF 82/160 reads (51%) | called by muse, mutect2, varscan2
